Somatic mutation profile of tumor specimen 0DWNTR from CCDI case PBCNUV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.0 years (1,476 days).
Specimen 0DWNTR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b9c0301-61a4-4ffc-a66b-9d88c68c2c43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNR2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59fbd027-641b-4180-a75c-a2c487130b2d

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 5'UTR 2, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP91 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 46/768 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs200730852; called by muse, mutect2
- KCNH3 | c.1571A>G p.Y524C | Missense Mutation (SNP) | VAF 160/241 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV57792172; called by muse, mutect2, varscan2
- ADAMTS16 | c.2168A>G p.D723G | Missense Mutation (SNP) | VAF 209/800 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- BABAM2 | c.450G>C p.Q150H | Missense Mutation (SNP) | VAF 50/877 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.291); called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 32/868 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- DMWD | c.1690C>G p.P564A | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- IRAG2 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 96/557 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYO6 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 41/931 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.029); called by muse, mutect2
- SERPINB8 | c.769A>T p.I257F | Missense Mutation (SNP) | VAF 52/900 reads (6%) | called by muse, mutect2
- ADCY10 | c.4632G>A p.Q1544= | Silent (SNP) | VAF 156/557 reads (28%) | catalogued as rs143562121; called by muse, mutect2, varscan2
- DCST1 | c.495C>T p.S165= | Silent (SNP) | VAF 154/519 reads (30%) | called by muse, mutect2, varscan2
- LMO7 | c.276C>T p.G92= (on ENST00000357063; = p.G107= on NM_005358.5) | Silent (SNP) | VAF 98/651 reads (15%) | catalogued as rs73536580, COSV58550865; called by muse, mutect2, varscan2
- RIOK2 | c.1446G>A p.L482= | Silent (SNP) | VAF 162/601 reads (27%) | called by muse, mutect2, varscan2
- COX7A2L | c.-745C>T | 5'UTR (SNP) | VAF 103/347 reads (30%) | catalogued as rs1005345612; called by muse, mutect2, varscan2
- FAM104B | c.-60G>T | 5'UTR (SNP) | VAF 83/157 reads (53%) | called by muse, mutect2, varscan2
- MFRP | chr11:119346485 C>T | 5'Flank (SNP) | VAF 25/410 reads (6%) | called by muse, mutect2
- PCID2 | c.37-96G>T | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as COSV55814251; called by muse, mutect2
- TSPAN16 | c.687+3621C>T | Intron (SNP) | VAF 111/458 reads (24%) | called by muse, mutect2, varscan2
